Somatic mutation profile of tumor specimen TCGA-CG-5722-01A (aliquot TCGA-CG-5722-01A-21D-1600-08) from TCGA case TCGA-CG-5722, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 67.0 years (24,472 days).
Specimen TCGA-CG-5722-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a3f979e-f9e7-4b57-9f0b-e439b6ba0ebf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-5722-11A (Solid Tissue Normal), aliquot TCGA-CG-5722-11A-02D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f381ab1-6417-45ed-8a1e-c083d9560cd7

The open-access MAF lists 87 somatic variants for this specimen: 66 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 59, Silent 21, Nonsense Mutation 5, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 13/105 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACE | c.2911C>T p.R971W | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769406157, COSV52007089; called by muse, mutect2, varscan2
- ACTRT1 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 76/353 reads (22%) | catalogued as COSV64420098; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4299G>A p.W1433* | Nonsense Mutation (SNP) | VAF 27/241 reads (11%) | catalogued as rs1330920617, COSV54470920; called by muse, mutect2
- AKAP3 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs370794366; called by muse, mutect2, varscan2
- ALKBH5 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 36/494 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.991); catalogued as COSV67687270; called by muse, mutect2
- APOBEC1 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as rs749139535, COSV57550081; called by muse, mutect2, varscan2
- ARHGEF15 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV62726556; called by muse, mutect2, varscan2
- BAZ2A | c.1436C>A p.A479E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV51644157; called by muse, mutect2, varscan2
- BCLAF3 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV61415175; called by muse, mutect2
- C19orf18 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1266990636, COSV58707582; called by muse, mutect2
- CD53 | c.623G>T p.C208F | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54763335; called by muse, mutect2
- CDS1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 23/465 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs771001468, COSV55687144, COSV55687463; called by muse, mutect2
- CENPI | c.2180G>A p.G727E | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as COSV54506645; called by muse, mutect2, varscan2
- CHTF18 | c.1900C>T p.R634C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs751286984, COSV50210212; called by muse, mutect2, varscan2
- COL12A1 | c.6242T>C p.I2081T | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.324); catalogued as COSV59408607; called by muse, mutect2
- DNAH14 | c.728T>C p.L243S (on ENST00000445597; = p.L66S on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs774051636, COSV64780969; called by muse, mutect2, varscan2
- EPHA8 | c.2639C>T p.A880V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as rs764652650, COSV51297479; called by muse, mutect2, varscan2
- FEM1A | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54164957; called by muse, mutect2, varscan2
- FHOD3 | c.3893C>G p.P1298R (on ENST00000359247 / NM_001281739.3; = p.P1315R on NM_025135.5) | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV99943217; called by muse, mutect2, varscan2
- FLYWCH2 | c.161T>G p.V54G | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.186); catalogued as COSV53559957; called by muse, mutect2, varscan2
- GJD2 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 33/294 reads (11%) | catalogued as rs749647277, COSV51747639; called by muse, mutect2, varscan2
- GJD4 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.44); catalogued as COSV58702412; called by muse, mutect2, varscan2
- GRIK1 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV58730945, COSV58732839; called by muse, mutect2, varscan2
- HNRNPD | c.772A>G p.M258V | Missense Mutation (SNP) | VAF 62/498 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV58314918; called by muse, mutect2, varscan2
- HOXA11 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.105); catalogued as COSV99136133; called by muse, mutect2, varscan2
- HUWE1 | c.1031G>T p.S344I | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.757); catalogued as COSV53364762; called by muse, mutect2, varscan2
- IRX5 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.113); catalogued as rs781126921, COSV58059571, COSV58060055; called by muse, mutect2
- KALRN | c.8300A>T p.D2767V (on ENST00000360013 / NM_001024660.4; = p.D1070V on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV52265040; called by muse, mutect2, varscan2
- KCNQ5 | c.2078C>T p.T693M | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs777062053, COSV59649876; called by muse, mutect2, varscan2
- KLK1 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 7/69 reads (10%) | catalogued as COSV56828716; called by muse, mutect2, varscan2
- LRRC37B | c.1619A>G p.Q540R | Missense Mutation (SNP) | VAF 50/241 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as COSV58955112; called by muse, mutect2, varscan2
- MYO9A | c.2428A>T p.R810* | Nonsense Mutation (SNP) | VAF 16/174 reads (9%) | catalogued as COSV61858435; called by muse, mutect2
- NBEA | c.6524C>T p.T2175M | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs1405928095, COSV59780924; called by muse, mutect2, varscan2
- NEXMIF | c.1661T>G p.M554R | Missense Mutation (SNP) | VAF 25/269 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50129241; called by muse, mutect2, varscan2
- NFE2L2 | c.641C>A p.P214Q | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as COSV67962627; called by muse, mutect2, varscan2
- NR3C1 | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.508); catalogued as rs370839677; called by muse, mutect2
- NUDT10 | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0.075); catalogued as COSV100726854; called by muse, mutect2, varscan2
- OR2T12 | c.946G>T p.A316S | Missense Mutation (SNP) | VAF 32/367 reads (9%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV58779699; called by muse, mutect2
- PCDHA1 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); catalogued as COSV65375143; called by muse, mutect2, varscan2
- PCDHA6 | c.609G>T p.E203D | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782260049, COSV65352562, COSV65358172; called by muse, mutect2, varscan2
- PIGS | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 13/268 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0.129); catalogued as rs758756650, COSV52026657; called by muse, mutect2
- POLH | c.1576A>G p.T526A | Missense Mutation (SNP) | VAF 8/197 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1249764640, COSV64781109; called by muse, mutect2
- RAMP3 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs771410083, COSV54245575; called by muse, mutect2
- RASSF3 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs762507850, COSV51688059; called by muse, mutect2, varscan2
- RIC1 | c.3752A>G p.E1251G | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV52605099, COSV52615780; called by muse, mutect2, varscan2
- SAMD7 | c.341T>A p.I114N | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1276225934, COSV59421756; called by muse, mutect2, varscan2
- SIPA1L1 | c.2870G>A p.R957Q | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs946552795, COSV62171928; called by muse, mutect2, varscan2
- SIPA1L2 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs749117335, COSV53385818; called by muse, mutect2
- SLC16A14 | c.1007A>G p.H336R | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV54621511; called by muse, mutect2, varscan2
- SYNE1 | c.11429C>T p.T3810M (on ENST00000367255 / NM_182961.4; = p.T3795M on NM_033071.3) | Missense Mutation (SNP) | VAF 41/385 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.277); catalogued as rs375577011, COSV55110141; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE2 | c.1902C>G p.F634L | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV59971305; called by muse, mutect2
- TCEAL5 | c.362A>C p.D121A | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65503612; called by muse, mutect2
- TLL1 | c.2599C>T p.R867W | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs760021584, COSV50262509; called by muse, mutect2, varscan2
- TMEM130 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); catalogued as rs782402178, COSV59561227; called by muse, mutect2, varscan2
- TTN | c.79819C>G p.P26607A (on ENST00000591111; = p.P19183A on NM_003319.4) | Missense Mutation (SNP) | VAF 32/396 reads (8%) | PolyPhen benign (0); catalogued as COSV60328471, COSV60364506; called by muse, mutect2
- TTN | c.24538C>T p.R8180C (on ENST00000591111; = p.R7253C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/116 reads (16%) | PolyPhen possibly damaging (0.867); catalogued as rs369517119, COSV60243203; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VEPH1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs751210034, COSV62882851; called by muse, mutect2
- WDR19 | c.3465C>A p.H1155Q | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99975984; called by muse, mutect2
- ZMAT1 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 46/508 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.331); catalogued as COSV65660198; called by muse, mutect2
- ZNF529 | c.375C>A p.S125R | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.117); catalogued as COSV61902132; called by muse, mutect2
- ZNF559-ZNF177 | c.763A>G p.K255E | Missense Mutation (SNP) | VAF 23/293 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.209); catalogued as COSV58674783; called by muse, mutect2
- ANKRD55 | c.1402del p.Q468Sfs*13 | Frame Shift Del (DEL) | VAF 25/189 reads (13%) | called by mutect2, pindel, varscan2
- TRGV4 | c.315A>C p.E105D | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- UHRF1BP1 | c.3215+2dup p.X1072_splice | Splice Site (INS) | VAF 37/263 reads (14%) | called by mutect2, pindel, varscan2
- ZNF658 | c.196C>G p.P66A | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2
- ARHGEF15 | c.780C>T p.A260= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs768476171, COSV62725029, COSV62725049; called by muse, mutect2, varscan2
- DLG4 | c.369G>A p.V123= (on ENST00000399506 / NM_001321075.3; = p.V166= on NM_001365.4) | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV57242327; called by muse, mutect2, varscan2
- FAM47B | c.183C>A p.A61= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as COSV61456960; called by muse, mutect2, varscan2
- FAM78A | c.309C>T p.Y103= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as rs1335557027, COSV64845199; called by muse, mutect2
- GRIN2A | c.135C>T p.D45= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as COSV58056621; called by muse, mutect2, varscan2
- IDNK | c.303A>C p.V101= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV52892673; called by muse, mutect2, varscan2
- MACC1 | c.1743C>T p.L581= | Silent (SNP) | VAF 40/348 reads (11%) | catalogued as rs552475136, COSV60546648; called by muse, mutect2, varscan2
- NRK | c.3519A>G p.E1173= | Silent (SNP) | VAF 9/248 reads (4%) | catalogued as COSV54607387, COSV99689315; called by muse, mutect2
- OR4D10 | c.243T>C p.V81= | Silent (SNP) | VAF 74/319 reads (23%) | catalogued as COSV73260215; called by muse, mutect2, varscan2
- OR51T1 | c.924G>T p.L308= | Silent (SNP) | VAF 11/143 reads (8%) | catalogued as COSV59028263; called by muse, mutect2
- PCDHA8 | c.1929G>A p.P643= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as rs1389332589, COSV65333190; called by muse, mutect2, varscan2
- PCDHGB2 | c.1302C>A p.S434= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as COSV54038652; called by muse, mutect2, varscan2
- PLXNB2 | c.5292G>A p.Q1764= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as rs776854618, COSV63784561; called by muse, mutect2, varscan2
- RIMS2 | c.1360C>T p.L454= (on ENST00000666250 / NM_001348490.2; = p.L262= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as COSV51726033; called by muse, mutect2, varscan2
- RNF139 | c.1359C>T p.L453= | Silent (SNP) | VAF 63/563 reads (11%) | catalogued as COSV52682391; called by muse, mutect2, varscan2
- SLC12A6 | c.3198A>G p.E1066= (on ENST00000354181 / NM_001365088.1; = p.E1015= on NM_005135.2) | Silent (SNP) | VAF 37/263 reads (14%) | catalogued as COSV51632300; called by muse, mutect2, varscan2
- TOMM34 | c.768G>A p.L256= | Silent (SNP) | VAF 32/254 reads (13%) | catalogued as COSV53843219; called by muse, mutect2, varscan2
- TSHZ3 | c.1203C>T p.L401= | Silent (SNP) | VAF 28/356 reads (8%) | catalogued as rs764196665, COSV53683317; called by muse, mutect2
- ZBTB14 | c.942C>T p.F314= | Silent (SNP) | VAF 7/120 reads (6%) | catalogued as COSV63697371; called by muse, mutect2
- ZNF229 | c.1182C>G p.V394= | Silent (SNP) | VAF 43/223 reads (19%) | catalogued as COSV52165309, COSV52165333; called by muse, mutect2, varscan2
- ZNRF4 | c.702G>A p.A234= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs549716057, COSV55776396; called by muse, mutect2, varscan2
